Somatic mutation profile of tumor specimen C3N-00439-02 (aliquot CPT0379480010) from CPTAC case C3N-00439, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.6 years (25,788 days).
Specimen C3N-00439-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5e349da-2209-4854-a76f-e8d6dee6b949.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00439-31 (Blood Derived Normal), aliquot CPT0379570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcce7c65-4f90-454c-84d1-8c54b37f9ab0

The open-access MAF lists 157 somatic variants for this specimen: 114 protein-altering or splice-affecting, 19 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 19, Intron 15, Frame Shift Del 11, Splice Site 5, 3'UTR 4, RNA 3, Nonsense Mutation 2, Splice Region 2, Frame Shift Ins 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3749T>C p.M1250T | Missense Mutation (SNP) | VAF 106/460 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913245, CM992181, COSV59255872; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP5B1 | c.2069T>C p.I690T | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs1195488989; called by muse, mutect2, varscan2
- ATP13A5 | c.2542T>C p.C848R | Missense Mutation (SNP) | VAF 148/390 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV60865207; called by muse, mutect2, varscan2
- ATXN7L1 | c.34_35del p.S12Gfs*69 | Frame Shift Del (DEL) | VAF 56/256 reads (22%) | catalogued as rs1458563663; called by pindel, varscan2
- COASY | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs769360620, COSV99888272; called by muse, mutect2, varscan2
- COL4A3 | c.1091C>G p.P364R | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV67412870; called by muse, mutect2, varscan2
- CORO2B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230243277; called by muse, mutect2, varscan2
- CSPP1 | c.842T>A p.I281N (on ENST00000676605; = p.I240N on NM_024790.6) | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV51582940; called by muse, mutect2, varscan2
- EHMT1 | c.884C>G p.T295S | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV58373378; called by muse, mutect2, varscan2
- FBXW7 | c.1342G>A p.A448T (on ENST00000281708 / NM_001349798.2; = p.A368T on NM_018315.5) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV55892614; called by muse, mutect2, varscan2
- GRM8 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as rs148553836, COSV100286014; called by muse, mutect2, varscan2
- MAP3K20 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as COSV100169005; called by muse, mutect2
- MYL3 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 167/463 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV52767323; called by muse, mutect2, varscan2
- NT5C3A | c.263T>A p.L88H (on ENST00000610140 / NM_001374335.1; = p.L54H on NM_016489.13) | Missense Mutation (SNP) | VAF 106/182 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385827802; called by muse, mutect2, varscan2
- OR5M1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs768719281, COSV101591625; called by muse, mutect2, varscan2
- PTPRN | c.819del p.Q274Kfs*44 | Frame Shift Del (DEL) | VAF 167/536 reads (31%) | catalogued as rs1289944567; called by mutect2, pindel, varscan2
- RUNDC3A | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 151/298 reads (51%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV99842096; called by muse, mutect2, varscan2
- SC5D | c.344-4C>T | Splice Region (SNP) | VAF 55/160 reads (34%) | catalogued as rs762996340, COSV50613065; called by muse, mutect2, varscan2
- SCART1 | c.2525G>A p.G842D | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471110341; called by muse, mutect2, varscan2
- SORBS2 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 125/274 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376986702; called by muse, mutect2, varscan2
- STAB2 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs1198203961, COSV66335620; called by muse, mutect2, varscan2
- UBASH3A | c.1141A>T p.R381W | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as COSV99369291; called by muse, mutect2, varscan2
- UBASH3A | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.635); catalogued as COSV52312352; called by muse, mutect2, varscan2
- ZFP36L2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 273/722 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56698042, COSV56698102; called by muse, mutect2, varscan2
- AASDH | c.2535A>C p.E845D | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ABAT | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 285/656 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAA1 | c.1158G>T p.Q386H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- AP3B2 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 149/359 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ARHGAP17 | c.1713del p.G572Afs*26 | Frame Shift Del (DEL) | VAF 47/150 reads (31%) | called by mutect2, pindel, varscan2
- ATAD2B | c.1589T>C p.L530P | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC6 | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CEMIP | c.3289C>G p.H1097D | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CITED2 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 178/489 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CLVS2 | c.829A>C p.N277H | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- COPS2 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, varscan2
- CSNK1D | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 214/816 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- DDX17 | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- DKK4 | c.496T>A p.C166S | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLEC1 | c.4484G>T p.G1495V | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DMRTA2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH7 | c.4140_4142del p.D1380del | In Frame Del (DEL) | VAF 29/79 reads (37%) | called by pindel, varscan2
- DPYSL4 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- DZIP1L | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 162/422 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- EEF2K | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFNB2 | c.490_497del p.V164Rfs*11 | Frame Shift Del (DEL) | VAF 76/203 reads (37%) | called by mutect2, pindel, varscan2
- EML3 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ESPL1 | c.576del p.P193Qfs*7 | Frame Shift Del (DEL) | VAF 124/553 reads (22%) | called by mutect2, pindel, varscan2
- ESYT3 | c.2021G>C p.R674T | Missense Mutation (SNP) | VAF 125/290 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXL13 | c.939_945dup p.Y316Lfs*45 | Frame Shift Ins (INS) | VAF 66/368 reads (18%) | called by mutect2, varscan2
- FBXO22 | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FGD3 | c.1036-6_1036-1del p.X346_splice | Splice Site (DEL) | VAF 73/292 reads (25%) | called by mutect2, pindel, varscan2
- GABRA3 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 194/234 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GMPPB | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- GRIA4 | c.1567T>G p.S523A | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HAAO | c.482del p.P161Lfs*12 | Frame Shift Del (DEL) | VAF 54/186 reads (29%) | called by mutect2, pindel, varscan2
- HIPK2 | c.20_26del p.G7Afs*20 | Frame Shift Del (DEL) | VAF 55/110 reads (50%) | called by mutect2, pindel, varscan2
- HNRNPH1 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HSBP1L1 | c.213+2T>C p.X71_splice | Splice Site (SNP) | VAF 30/41 reads (73%) | called by muse, mutect2, varscan2
- IGF2R | c.1546_1547del p.I516* | Frame Shift Del (DEL) | VAF 68/210 reads (32%) | called by mutect2, pindel, varscan2
- IGHV3-48 | c.26T>G p.F9C | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ITSN2 | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNC4 | c.1623G>C p.K541N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- KPNA3 | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LAMB1 | c.2488A>C p.N830H | Missense Mutation (SNP) | VAF 204/354 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIPE | c.707C>G p.S236* | Nonsense Mutation (SNP) | VAF 73/160 reads (46%) | called by muse, mutect2, varscan2
- LPIN3 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LRP2 | c.11500A>C p.T3834P | Missense Mutation (SNP) | VAF 132/385 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MAP3K5 | c.437T>A p.F146Y | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MICALL1 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 101/325 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC3 | c.325A>T p.M109L | Missense Mutation (SNP) | VAF 108/294 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTMR14 | c.1043T>C p.L348S | Missense Mutation (SNP) | VAF 162/418 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO16 | c.2285_2286insA p.S762Rfs*4 | Frame Shift Ins (INS) | VAF 34/131 reads (26%) | called by mutect2, pindel, varscan2
- NAA15 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NADSYN1 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBPF10 | c.1085_1091+6del p.X362_splice | Splice Site (DEL) | VAF 37/275 reads (13%) | called by mutect2, pindel, varscan2
- NBPF11 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 304/854 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NKAIN3 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUBP1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- NUGGC | c.2142T>A p.F714L | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSBPL1A | c.1680del p.E560Dfs*15 (on ENST00000319481 / NM_080597.4; = p.E47Dfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 41/73 reads (56%) | called by mutect2, pindel, varscan2
- OTUB2 | c.647T>G p.V216G | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PAN2 | c.1262+2T>C p.X421_splice | Splice Site (SNP) | VAF 76/125 reads (61%) | called by muse, mutect2, varscan2
- PDE3A | c.3074A>T p.K1025I | Missense Mutation (SNP) | VAF 182/640 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- PDIA6 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDZD2 | c.3409C>G p.P1137A | Missense Mutation (SNP) | VAF 130/351 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PEAR1 | c.577T>A p.C193S | Missense Mutation (SNP) | VAF 153/387 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PHF2 | c.3257del p.L1086* | Frame Shift Del (DEL) | VAF 37/133 reads (28%) | called by mutect2, pindel, varscan2
- PIP5KL1 | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, varscan2
- PITX2 | c.403A>C p.N135H (on ENST00000354925 / NM_001204397.1; = p.N142H on NM_000325.6) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- POLRMT | c.3482C>T p.S1161F | Missense Mutation (SNP) | VAF 107/260 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- POLRMT | c.822+1G>A p.X274_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- PRKCH | c.1153G>T p.V385L | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- PTPRJ | c.3911A>T p.D1304V | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PUS7L | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF112 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 160/483 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1L1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- RPS5 | c.494A>T p.N165I | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SAGE1 | c.2528A>G p.E843G | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by mutect2, varscan2
- SAMD9 | c.2839A>C p.K947Q | Missense Mutation (SNP) | VAF 321/593 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SCN4A | c.854del p.P285Rfs*119 | Frame Shift Del (DEL) | VAF 98/355 reads (28%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.2569A>C p.I857L | Missense Mutation (SNP) | VAF 158/380 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC4A2 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 217/425 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SMARCA2 | c.1915G>C p.D639H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SPIC | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, varscan2
- SYNE2 | c.4960T>A p.L1654I | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SZT2 | c.9559C>A p.L3187M (on ENST00000634258 / NM_001365999.1; = p.L3130M on NM_015284.4) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRANK1 | c.4336A>T p.R1446* | Nonsense Mutation (SNP) | VAF 106/230 reads (46%) | called by muse, mutect2, varscan2
- TRIOBP | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 278/799 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- UBE4A | c.3188A>C p.E1063A (on ENST00000252108 / NM_001204077.2; = p.E1070A on NM_004788.4) | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WDR41 | c.524-5T>A | Splice Region (SNP) | VAF 59/144 reads (41%) | called by muse, mutect2, varscan2
- XYLB | c.138T>A p.F46L | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- YLPM1 | c.4180A>G p.M1394V | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFYVE9 | c.3232C>A p.L1078I | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF586 | c.149T>A p.L50H | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRG5 | c.18C>T p.A6= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs1280932049; called by muse, mutect2, varscan2
- ARHGEF2 | c.1608A>G p.K536= (on ENST00000361247 / NM_001162383.2; = p.K508= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 87/226 reads (38%) | called by muse, mutect2, varscan2
- BMP7 | c.1122C>A p.T374= | Silent (SNP) | VAF 175/420 reads (42%) | called by muse, mutect2, varscan2
- COL6A3 | c.2172C>T p.S724= | Silent (SNP) | VAF 109/277 reads (39%) | called by muse, mutect2, varscan2
- CRYZL1 | c.552C>T p.C184= | Silent (SNP) | VAF 46/133 reads (35%) | called by muse, mutect2, varscan2
- DOCK8 | c.1026C>T p.D342= | Silent (SNP) | VAF 143/380 reads (38%) | called by muse, mutect2, varscan2
- ECPAS | c.4384C>A p.R1462= | Silent (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2, varscan2
- GLB1L | c.99T>C p.D33= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- ILKAP | c.312C>A p.I104= | Silent (SNP) | VAF 83/194 reads (43%) | called by muse, mutect2, varscan2
- ITGB2 | c.1737G>A p.G579= (on ENST00000302347; = p.G555= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 137/388 reads (35%) | catalogued as rs990368825; called by muse, mutect2, varscan2
- LPIN3 | c.897G>A p.Q299= | Silent (SNP) | VAF 99/339 reads (29%) | catalogued as rs760985042; called by muse, mutect2, varscan2
- MED13L | c.5101T>C p.L1701= | Silent (SNP) | VAF 176/670 reads (26%) | called by muse, mutect2, varscan2
- MFSD12 | c.702A>C p.L234= | Silent (SNP) | VAF 114/313 reads (36%) | called by muse, mutect2, varscan2
- PDE3B | c.2295T>C p.N765= | Silent (SNP) | VAF 56/132 reads (42%) | called by muse, mutect2, varscan2
- PEAR1 | c.576G>A p.Q192= | Silent (SNP) | VAF 154/394 reads (39%) | called by muse, mutect2, varscan2
- PIP5KL1 | c.411G>A p.K137= | Silent (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- TMEM184B | c.63G>A p.S21= | Silent (SNP) | VAF 70/215 reads (33%) | catalogued as rs148242477; called by muse, mutect2, varscan2
- WNK1 | c.732C>G p.T244= | Silent (SNP) | VAF 94/559 reads (17%) | called by muse, mutect2, varscan2
- ZNF853 | c.1317C>G p.G439= | Silent (SNP) | VAF 71/267 reads (27%) | catalogued as rs1314167681; called by muse, mutect2, varscan2
- ADAMTS8 | c.-140C>T | 5'UTR (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- ATG3 | c.863+24_863+33del | Intron (DEL) | VAF 17/75 reads (23%) | called by pindel, varscan2
- CDK9 | c.605-9T>A | Intron (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- CLU | c.*834T>C | 3'UTR (SNP) | VAF 93/256 reads (36%) | called by muse, mutect2, varscan2
- DDX49 | c.448-69T>C | Intron (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- DUOXA1 | c.555-40A>C | Intron (SNP) | VAF 158/426 reads (37%) | called by muse, mutect2, varscan2
- ENTPD6 | c.1187-19G>C | Intron (SNP) | VAF 22/66 reads (33%) | catalogued as rs1414166566; called by muse, mutect2, varscan2
- FAM74A3 | n.262C>G | RNA (SNP) | VAF 244/1405 reads (17%) | called by muse, mutect2, varscan2
- KLHL20 | c.597+36_597+38del | Intron (DEL) | VAF 58/156 reads (37%) | called by pindel, varscan2
- LINC00692 | n.623T>A | RNA (SNP) | VAF 48/169 reads (28%) | catalogued as rs995568737; called by muse, mutect2, varscan2
- MRM2 | c.298+560del | Intron (DEL) | VAF 18/38 reads (47%) | called by mutect2, pindel
- NECTIN3 | c.160+262G>A | Intron (SNP) | VAF 40/92 reads (43%) | called by muse, varscan2
- OTUD6B | c.316-1629C>A | Intron (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- PITX2 | c.185-1120G>T | Intron (SNP) | VAF 140/355 reads (39%) | called by muse, mutect2, varscan2
- PML | c.1710+1533C>A | Intron (SNP) | VAF 154/445 reads (35%) | catalogued as rs779759818; called by muse, mutect2, varscan2
- POM121L4P | n.309G>A | RNA (SNP) | VAF 76/475 reads (16%) | catalogued as rs796092137; called by muse, mutect2, varscan2
- RB1 | c.718+18G>T | Intron (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- RB1 | c.718+19C>A | Intron (SNP) | VAF 24/86 reads (28%) | catalogued as rs764322235; called by muse, mutect2, varscan2
- SORBS2 | c.-197-5969G>T | Intron (SNP) | VAF 84/251 reads (33%) | called by muse, mutect2, varscan2
- TJP2 | c.1521-42A>C | Intron (SNP) | VAF 71/142 reads (50%) | called by muse, mutect2, varscan2
- TMEM225B | c.*3del | 3'UTR (DEL) | VAF 64/148 reads (43%) | called by mutect2, pindel, varscan2
- TRAPPC13 | c.*8T>C | 3'UTR (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- TRIM15 | c.*267C>G | 3'UTR (SNP) | VAF 54/126 reads (43%) | called by muse, mutect2, varscan2
- ZNF414 | chr19:8510947 C>T | 3'Flank (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
